MMRF case MMRF_1833 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/29d6fb90-cf93-4e01-b6c8-742c6e6b6dad

Demographics
Sex at birth: male; Race: white; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.0 years (22,279 days); ISS stage: I; Days to last known disease status: 1,072 days (2.9 years); Days to last follow up: 1,072 days (2.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 44 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 176 days; Days to treatment end: 360 days.
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,009 days (2.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 266 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 5.58 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 3.48 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 4.95 mmol/L.
- Day 99 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 102 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.23 mg/dL; Immunoglobulin G 3.3 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 3.75 µg/mL; Hemoglobin 7.44 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.05 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 6.44 mmol/L.
- Day 204 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 100 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 6.57 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 4.18 mmol/L.
- Day 260 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 177 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 3.83 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 8 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 4.73 mmol/L.
- Day 345 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 24.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 4.63 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 10.1 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 7.54 mmol/L.
- Day 452: Serum Free Immunoglobulin Light Chain, Kappa 16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.21 mg/dL; Immunoglobulin G 4.37 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.59 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 4.73 mmol/L.
- Day 551: Serum Free Immunoglobulin Light Chain, Kappa 5.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 4.91 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 4.9 mmol/L.
- Day 649: Serum Free Immunoglobulin Light Chain, Kappa 5.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 4.76 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 5.06 mmol/L.
- Day 739: Serum Free Immunoglobulin Light Chain, Kappa 5.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.78 mg/dL; Immunoglobulin G 6.65 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 9.3 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 4.62 mmol/L.
- Day 827 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 5.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.42 mg/dL; Immunoglobulin G 5.58 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.88 µg/mL; Hemoglobin 9.11 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 3.58 mmol/L.
- Day 925: Serum Free Immunoglobulin Light Chain, Kappa 15.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.43 mg/dL; Immunoglobulin G 5.83 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 9.18 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.5 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.06 mmol/L.
- Day 995: Serum Free Immunoglobulin Light Chain, Kappa 43.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Hemoglobin 9.05 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.5 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 6.05 mmol/L.
- Day 1,072: Serum Free Immunoglobulin Light Chain, Kappa 18.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.72 mg/dL; Immunoglobulin G 6.05 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.03 mmol/L; Glucose 4.68 mmol/L.

Other clinical attributes
- Day 1: Weight: 93 kg; Height: 182 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1833_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1833_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
